Somatic mutation profile of tumor specimen 079b5600-6afc-4785-bb22-48cfab (aliquot 079b5600-6afc-4785-bb22-48cfab_D6_1) from CPTAC case 11BR023, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.4 years (21,322 days).
Specimen 079b5600-6afc-4785-bb22-48cfab: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfb05db5-4670-40c3-b850-7e534dcec5d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 70ee4720-f4dc-4b91-a6aa-c0efd9 (Blood Derived Normal), aliquot 70ee4720-f4dc-4b91-a6aa-c0efd9_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc509072-b157-44a5-848b-d28aad3f475c

The open-access MAF lists 104 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 23, Intron 6, RNA 4, 5'UTR 3, Nonsense Mutation 3, 3'UTR 2, Frame Shift Del 1, Splice Site 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 84/171 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 30/231 reads (13%) | catalogued as rs118203427, CM981931, COSV53767064; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC8 | c.1810C>G p.L604V | Missense Mutation (SNP) | VAF 28/463 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1379054952; called by muse, mutect2
- ATF7IP | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as COSV99662256; called by muse, mutect2, varscan2
- COL20A1 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 106/313 reads (34%) | catalogued as rs1258752931; called by muse, mutect2, varscan2
- DOCK6 | c.5488G>C p.D1830H | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV99624642; called by muse, mutect2, varscan2
- DSPP | c.3472G>A p.D1158N | Missense Mutation (SNP) | VAF 144/310 reads (46%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.021); catalogued as rs767300996; called by mutect2, varscan2
- ERVW-1 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV71259462; called by muse, mutect2, varscan2
- GDF7 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs773731397; called by muse, mutect2, varscan2
- H2BC6 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs763821729, COSV61591826; called by muse, mutect2
- KALRN | c.2843C>T p.S948F | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53753346; called by muse, mutect2, varscan2
- PLEC | c.13624C>T p.R4542C (on ENST00000322810 / NM_201380.4; = p.R4432C on NM_000445.5) | Missense Mutation (SNP) | VAF 48/762 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781837848; ClinVar: uncertain significance; called by muse, mutect2
- PNPLA8 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.138); catalogued as rs148695833, COSV57554664; called by muse, mutect2, varscan2
- PSKH1 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 33/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52123977; called by muse, mutect2
- RICTOR | c.3151C>T p.R1051W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs773279594; called by muse, mutect2, varscan2
- SGSM2 | c.2918_2920del p.I973del (on ENST00000426855 / NM_001098509.2; = p.I1018del on NM_014853.3) | In Frame Del (DEL) | VAF 20/130 reads (15%) | catalogued as rs751168239; called by pindel, varscan2
- SHANK2 | c.3004G>A p.V1002I | Missense Mutation (SNP) | VAF 123/2956 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs782310841, COSV53603667; called by muse, mutect2
- SKOR2 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV68550130; called by muse, mutect2, varscan2
- SLC23A2 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309062012; called by muse, mutect2
- SLC35E2B | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as rs759941666; called by muse, mutect2, varscan2
- SPTA1 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 61/568 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372067263, COSV63749356; called by muse, mutect2, varscan2
- USP7 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as COSV61213059; called by muse, mutect2
- YLPM1 | c.3124G>A p.G1042S | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as rs760284725; called by muse, mutect2
- ZMIZ1 | c.2019+1G>A p.X673_splice | Splice Site (SNP) | VAF 49/329 reads (15%) | catalogued as COSV99071557; called by muse, mutect2, varscan2
- ABCA6 | c.962T>A p.L321Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ABHD13 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- AHNAK | c.13596G>C p.K4532N | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASPM | c.7333A>G p.I2445V | Missense Mutation (SNP) | VAF 84/625 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, varscan2
- BORCS5 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCDC183 | c.1570G>C p.G524R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CCDC30 | c.2237T>C p.V746A (on ENST00000340612; = p.V703A on NM_001080850.3) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CCNYL1 | c.736G>A p.V246I (on ENST00000295414 / NM_001330218.2; = p.V176I on NM_152523.2) | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2
- CDCA2 | c.692C>G p.T231R | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2
- CGRRF1 | c.965A>T p.K322I | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- COX15 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCTN1 | c.3532G>T p.A1178S | Missense Mutation (SNP) | VAF 20/539 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- DNMT3A | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EVPL | c.2647A>G p.K883E | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAM8A1 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- FCER1A | c.633G>C p.L211F | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- FKBP2 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- GALR2 | c.1094A>T p.E365V | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2AC6 | c.361A>T p.T121S | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCLS1 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- HUNK | c.1309A>C p.K437Q | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.154); called by muse, mutect2
- KCNQ1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 24/483 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- MAP2K7 | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTCL1 | c.5463G>C p.E1821D (on ENST00000306329 / NM_001378206.1; = p.E1502D on NM_015210.4) | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MYO7B | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NWD1 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARG | c.1480G>C p.V494L | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2
- PRKACB | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RYR1 | c.6695G>T p.C2232F | Missense Mutation (SNP) | VAF 210/760 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA31D1 | c.2313T>A p.N771K | Missense Mutation (SNP) | VAF 71/334 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TMEM263 | c.140A>T p.K47M | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMEM269 | c.580G>C p.E194Q (on ENST00000536543; = p.E152Q on NM_001354602.1) | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TSKS | c.1648C>G p.L550V | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTN | c.19000G>C p.D6334H (on ENST00000591111; = p.D5407H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/65 reads (6%) | PolyPhen probably damaging (0.988); called by muse, mutect2
- TYK2 | c.3554G>A p.S1185N | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2
- UFL1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- VSIG8 | c.760del p.V254* | Frame Shift Del (DEL) | VAF 78/201 reads (39%) | called by mutect2, pindel, varscan2
- WDR11 | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF311 | c.1556G>T p.R519I | Missense Mutation (SNP) | VAF 36/756 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.283); called by muse, mutect2
- ZNF638 | c.3879G>T p.K1293N | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF766 | c.1023C>A p.S341R | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.396); called by muse, mutect2
- BMPR1B | c.36C>T p.G12= | Silent (SNP) | VAF 60/161 reads (37%) | catalogued as rs936793430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.1995G>A p.L665= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV64191287; called by muse, mutect2
- CACNA1S | c.612C>G p.L204= | Silent (SNP) | VAF 214/521 reads (41%) | catalogued as COSV100755241; called by muse, mutect2, varscan2
- CRLF3 | c.501G>A p.V167= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as rs998043777, COSV100158291; called by muse, mutect2, varscan2
- DENND2A | c.2310C>T p.F770= | Silent (SNP) | VAF 45/313 reads (14%) | called by muse, mutect2, varscan2
- DSG2 | c.1329C>G p.V443= | Silent (SNP) | VAF 35/228 reads (15%) | called by muse, mutect2, varscan2
- HELZ2 | c.580C>T p.L194= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- ITIH3 | c.1731G>A p.E577= | Silent (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- KALRN | c.2844C>T p.S948= | Silent (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- MAP2K7 | c.1029G>T p.L343= | Silent (SNP) | VAF 25/258 reads (10%) | catalogued as rs763221799; called by muse, mutect2
- NCOA1 | c.2967C>T p.N989= | Silent (SNP) | VAF 12/233 reads (5%) | catalogued as rs1203007308; called by muse, mutect2
- OR10A3 | c.111G>A p.V37= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- OR52K2 | c.73C>T p.L25= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PCYOX1 | c.1263C>T p.L421= | Silent (SNP) | VAF 96/346 reads (28%) | called by muse, mutect2, varscan2
- PLEC | c.10632G>A p.L3544= (on ENST00000322810 / NM_201380.4; = p.L3434= on NM_000445.5) | Silent (SNP) | VAF 49/233 reads (21%) | catalogued as rs797044719; called by muse, mutect2, varscan2
- PWP1 | c.1230G>A p.V410= | Silent (SNP) | VAF 25/169 reads (15%) | called by muse, mutect2, varscan2
- SCRIB | c.2370C>T p.G790= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as rs369961761; called by muse, mutect2
- SERPINB10 | c.723C>G p.L241= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs1219023663; called by muse, mutect2
- SKOR2 | c.396C>T p.G132= | Silent (SNP) | VAF 111/735 reads (15%) | catalogued as rs749462279; called by muse, mutect2, varscan2
- SLC24A5 | c.228C>T p.I76= | Silent (SNP) | VAF 44/434 reads (10%) | catalogued as rs762176351, COSV58316211; called by muse, mutect2, varscan2
- SLC4A2 | c.798C>T p.A266= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs1181036024; called by muse, mutect2
- TRAK2 | c.2247C>G p.G749= | Silent (SNP) | VAF 97/312 reads (31%) | called by muse, mutect2, varscan2
- TUBA3C | c.555C>T p.Y185= | Silent (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- AC079612.1 | n.275G>A | RNA (SNP) | VAF 26/485 reads (5%) | called by muse, mutect2
- AGAP7P | n.307C>G | RNA (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2, varscan2
- AL008638.2 | n.373C>G | RNA (SNP) | VAF 48/221 reads (22%) | called by muse, mutect2, varscan2
- B3GNT4 | c.*1228_*1234del | 3'UTR (DEL) | VAF 131/455 reads (29%) | called by mutect2, pindel, varscan2
- BMERB1 | chr16:15591092 G>A | 3'Flank (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- DNMBP | c.2261-4855T>G | Intron (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- EHF | c.-4+1150_-4+1154del | Intron (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- GRM7 | c.-111A>G | 5'UTR (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- MAP2K3 | c.960+20G>A | Intron (SNP) | VAF 41/179 reads (23%) | catalogued as rs770311346; called by muse, mutect2, varscan2
- MCRIP1 | c.-48-1386C>G | Intron (SNP) | VAF 30/277 reads (11%) | called by muse, mutect2, varscan2
- MIR892A | n.43G>T | RNA (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- MYBL2 | c.*4G>A | 3'UTR (SNP) | VAF 58/142 reads (41%) | catalogued as rs747063275; called by muse, mutect2, varscan2
- PHC3 | c.-12C>A | 5'UTR (SNP) | VAF 20/67 reads (30%) | catalogued as COSV71923704; called by muse, mutect2, varscan2
- SCARB2 | c.-45T>C | 5'UTR (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
- VPS9D1 | c.176-37G>C | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- VPS9D1 | c.176-697G>C | Intron (SNP) | VAF 61/142 reads (43%) | catalogued as rs1355314563, COSV99235521; called by muse, varscan2
